Gene-level copy-number profile of specimen HCM-BROD-1121-C71-85A from HCMI case HCM-BROD-1121-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.5 years (25,400 days).
Specimen HCM-BROD-1121-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 189475b1-debe-4148-974d-073be5e84549.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-1121-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,250 have no estimate.
https://portal.gdc.cancer.gov/files/4e15e738-8b91-42fe-a0b4-c392291cb31c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 2: 3,677; copy number 3: 1,012; copy number 4: 44,509; copy number 5: 2,199; copy number 6: 6,777; copy number 7: 1; copy number 8: 167; copy number 9: 7; copy number 10: 8.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:31,008,497–31,538,211, 16 genes (within-gene range 0–2): AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,633,140–89,933,250, 1 gene, copy number 10 (within-gene range 6–10): AC093423.3.
- chr1:89,788,914–90,035,533, 7 genes, copy number 10: AC099568.1, AC099568.2, LRRC8D, AL391497.1, RN7SKP272, GEMIN8P4, ZNF326.
- chr1:91,260,766–91,644,082, 7 genes, copy number 9: HFM1, Y_RNA, FEN1P1, CDC7, WDR82P2, AL714022.1, HSP90B3P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
